Surgical pathology report (de-identified scan), TCGA case TCGA-24-1852, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1852-02A (Recurrent Tumor).

[page 1 of 2]
Patient Name:

DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient Name:

Address:

Gender: F

DOB:

Service:

Location

MRN:

Hospital #:

Patient

Accession

Taken

Receive

Reported:

Physician(s):

Other Related Clinical Data:

ICB-0-3
Carcinoma, serous, papillary 8461/3
Site: peritoneum, NOS C48.2

hw
1/26/15

DIAGNOSIS:

LARGE INTESTINE, "SMALL BOWEL NODULE," EXCISION

- SEGMENT OF COLON WITH EXTENSIVE MURAL METASTATIC PAPILLARY SEROUS CARCINOMA

LYMPH NODE, "LEFT COMMON," EXCISION

- ONE LYMPH NODE WITH NO EVIDENCE OF MALIGNANCY (0/1)

SOFT TISSUE, "PERITONEAL NODULES," BIOPSY

- FOCAL METASTATIC PAPILLARY SEROUS CARCINOMA

SOFT TISSUE, "PELVIC MASS," EXCISION

- METASTATIC PAPILLARY SEROUS CARCINOMA

SOFT TISSUE, "RIGHT PELVIC LYMPH NODE," EXCISION

- FIBROFATTY TISSUE WITH NO EVIDENCE OF MALIGNANCY

- NO LYMPHOID TISSUE IDENTIFIED

By this signature, I attest that the above diagnosis is based upon my
personal
examination of the slides(and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

History:

[page 2 of 2]
Patient Name:

DOB:

The patient is a year old woman with a history of ovarian papillary serous carcinoma, status post chemotherapy, who presents with an elevated CA125 and a pelvic mass. Operative procedure: Laparotomy and resection of pelvic mass.

Specimen(s) Received:

- A: SMALL BOWEL NODULE
- B: LEFT COMMON LYMPH NODES
- C: PERITONEAL NODULES
- D: PELVIC MASS TUMOR
- E: RIGHT PELVIC LYMPH NODES

Gross Description

The specimens are received in five formalin-filled containers, each labeled with the patient's name. The first container is labeled "small bowel nodule." It contains a single piece of soft, slightly friable, tan-pink tissue measuring 1.5 x 1.5 x 0.8 cm in greatest dimension. One side is smooth, and the opposite side has a vague papillary appearance. Sections show soft, somewhat friable, tan-white tissue. Labeled A1. Jar 1.

The second container is labeled "left common lymph nodes." It contains three pieces of tan-yellow and pink soft tissue ranging in size from 0.5 x 0.5 x 0.2 cm to 1.5 x 0.4 x 0.3 cm. A single homogeneous, tan-white lymph node is identified in the intermediate sized fragment measuring 0.8 x 0.4 x 0.3 cm. Labeled B1. Jar 1.

The third container is labeled "peritoneal nodules." It contains a single piece of membranous, tan-pink, smooth and glistening soft tissue, with attached soft, lobulated, yellow adipose tissue, measuring 3.0 x 3.0 x 0.4 cm in greatest dimension. Sections show no discrete tumor. Labeled C1 and C2. Jar 0.

The fourth container is labeled "pelvic mass/tumor." It contains a single piece of variegated, tan-pink, smooth soft tissue, with attached lobulated soft, yellow adipose tissue, measuring 5.0 x 4.0 x 1.5 cm in greatest dimension. Sections show a cystic cavity with scattered tan-white, soft nodules, with papillary excrescences on the surface of the nodules, ranging in size from 0.3 to 1.0 cm. Also present are fragments of friable, tan-brown tissue. Labeled D1 to D4. Jar 1.

The fifth container is labeled "right pelvic lymph nodes." It contains two pieces of dark-red/gray soft tissue measuring 0.4 x 0.4 x 0.2 cm and 2.0 x 0.5 x 0.2 cm. No lymph nodes are grossly identified. Labeled E1. Jar 0.

Source: NCI Genomic Data Commons file de0ce47a-82d2-44be-ac97-9b7c77792be6 (TCGA-24-1852.FC644609-4B3F-41A5-9164-BC024C95DAB0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).